Somatic mutation profile of tumor specimen TCGA-DJ-A3VM-01A (aliquot TCGA-DJ-A3VM-01A-11D-A23M-08) from TCGA case TCGA-DJ-A3VM, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 68.2 years (24,896 days).
Specimen TCGA-DJ-A3VM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76ffe1f7-de91-4928-acd3-3da602eeeb64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3VM-10A (Blood Derived Normal), aliquot TCGA-DJ-A3VM-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/caebf3f6-2c8e-4303-b7d3-ffdea0b2183d

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNOT10 | c.1526A>G p.H509R | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as rs201889112, COSV59395752; called by muse, mutect2, varscan2
- CTC1 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 76/170 reads (45%) | catalogued as COSV59855707; called by muse, mutect2, varscan2
- GUCY1A1 | c.391G>C p.V131L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV56657000; called by muse, mutect2, varscan2
- KCNIP4 | c.385T>G p.F129V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62858549; called by muse, mutect2
- LRRK2 | c.5357C>G p.S1786C | Missense Mutation (SNP) | VAF 163/450 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54161227, COSV54173172; called by muse, mutect2, varscan2
- MOGAT3 | c.641G>C p.G214A | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370137222; called by muse, mutect2, varscan2
- MYLK | c.5134C>T p.Q1712* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV60606538, COSV60623996; called by muse, mutect2
- NTNG2 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs753190951, COSV62367464, COSV62369130; called by muse, mutect2, varscan2
- NUP133 | c.1973C>T p.S658F | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as COSV54575778; called by muse, mutect2, varscan2
- SNRK | c.588A>T p.V196= | Splice Region (SNP) | VAF 56/154 reads (36%) | catalogued as COSV56071221; called by muse, mutect2, varscan2
- ATP9B | c.869_870del p.L290Rfs*32 | Frame Shift Del (DEL) | VAF 45/151 reads (30%) | called by mutect2, pindel, varscan2
- CPA2 | c.18C>T p.I6= | Silent (SNP) | VAF 86/219 reads (39%) | catalogued as COSV55981606; called by muse, mutect2, varscan2
- EIF3G | c.951G>A p.P317= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs199502040; called by muse, mutect2, varscan2
- PSPH | c.609A>G p.Q203= | Silent (SNP) | VAF 14/215 reads (7%) | catalogued as rs752178752, COSV51914195; called by muse, mutect2
- TG | c.450G>T p.G150= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV55096439; called by muse, mutect2, varscan2
